Somatic mutation profile of tumor specimen 0DRQT3 from CCDI case PBCGZA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: External ear; Age at diagnosis: 18.1 years (6,627 days).
Specimen 0DRQT3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0378051-4299-47c9-aaf3-4a5407817721.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRQSR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f8c6ad3-cd0d-405e-946f-067b4d3b9197

The open-access MAF lists 75 somatic variants for this specimen: 41 protein-altering or splice-affecting, 17 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 17, Intron 9, 3'UTR 5, Frame Shift Del 2, Nonsense Mutation 1, 5'UTR 1, Frame Shift Ins 1, 5'Flank 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 169/264 reads (64%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARHGAP44 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 116/364 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); catalogued as rs199982507; called by muse, mutect2, varscan2
- CACNA1E | c.4023G>T p.M1341I | Missense Mutation (SNP) | VAF 248/819 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as COSV62402735; called by mutect2, varscan2
- CUL9 | c.4247C>T p.A1416V | Missense Mutation (SNP) | VAF 195/454 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.311); catalogued as rs199813038; called by muse, mutect2, varscan2
- DPP10 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 149/596 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as rs757238978, COSV59678252; called by muse, mutect2, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 226/891 reads (25%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- ILF3 | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 75/251 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV104376471; called by muse, mutect2, varscan2
- KRT20 | c.973T>A p.L325I | Missense Mutation (SNP) | VAF 48/718 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1479182225; called by muse, mutect2
- MMP13 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 204/1048 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886569117, COSV52823611; called by muse, mutect2, varscan2
- MROH2B | c.1160T>C p.I387T | Missense Mutation (SNP) | VAF 239/815 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs540024081; called by muse, mutect2, varscan2
- NRXN2 | c.1598G>T p.S533I | Missense Mutation (SNP) | VAF 163/712 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1362446308; called by muse, mutect2, varscan2
- PHKA2 | c.2910G>A p.V970= | Splice Region (SNP) | VAF 124/374 reads (33%) | catalogued as rs147879086; called by muse, mutect2, varscan2
- RNF152 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 170/379 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.67); catalogued as COSV100455329; called by muse, mutect2, varscan2
- SDC1 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 95/375 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as rs750695100; called by muse, mutect2, varscan2
- STAB1 | c.1972C>G p.Q658E | Missense Mutation (SNP) | VAF 125/456 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.053); catalogued as rs867523024; called by muse, mutect2, varscan2
- WFDC8 | c.280C>A p.P94T | Missense Mutation (SNP) | VAF 130/584 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs753939878; called by muse, mutect2, varscan2
- ZNF425 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 123/410 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.758); catalogued as COSV65200509; called by muse, mutect2, varscan2
- ANKMY1 | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 200/790 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANKRD36 | c.3997C>T p.Q1333* | Nonsense Mutation (SNP) | VAF 98/905 reads (11%) | called by muse, mutect2, varscan2
- APOBR | c.2761G>T p.A921S (on ENST00000431282; = p.A930S on NM_018690.4) | Missense Mutation (SNP) | VAF 97/250 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ARCN1 | c.1051A>C p.K351Q | Missense Mutation (SNP) | VAF 228/1159 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CD2 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 193/819 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLEC14A | c.1238T>C p.L413S | Missense Mutation (SNP) | VAF 152/423 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH12 | c.5270C>T p.P1757L | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- EML6 | c.2811G>T p.K937N | Missense Mutation (SNP) | VAF 206/815 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- ETAA1 | c.613C>A p.L205I | Missense Mutation (SNP) | VAF 185/816 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- GBA | c.212C>G p.P71R | Missense Mutation (SNP) | VAF 90/1184 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- GNAI2 | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 166/645 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HLA-DMB | c.525G>C p.Q175H | Missense Mutation (SNP) | VAF 123/337 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCBP1 | c.722_723del p.K241Rfs*16 | Frame Shift Del (DEL) | VAF 118/392 reads (30%) | called by mutect2, pindel, varscan2
- OR52D1 | c.594T>A p.N198K | Missense Mutation (SNP) | VAF 121/552 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PFKFB1 | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 182/683 reads (27%) | PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PKD1L3 | c.3327A>T p.Q1109H | Missense Mutation (SNP) | VAF 216/616 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PLXNC1 | c.2837A>G p.Y946C | Missense Mutation (SNP) | VAF 165/685 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SCAMP2 | c.43G>T p.V15L | Missense Mutation (SNP) | VAF 86/203 reads (42%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCAPER | c.1999C>A p.Q667K | Missense Mutation (SNP) | VAF 177/482 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCG2 | c.968G>A p.S323N | Missense Mutation (SNP) | VAF 150/633 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC22A11 | c.1290dup p.V431Cfs*24 | Frame Shift Ins (INS) | VAF 109/560 reads (19%) | called by mutect2, pindel, varscan2
- TMEM39B | c.707G>C p.R236P | Missense Mutation (SNP) | VAF 310/597 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- USP11 | c.1105G>A p.A369T (on ENST00000218348; = p.A326T on NM_001371072.1) | Missense Mutation (SNP) | VAF 164/666 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF630 | c.652T>A p.S218T | Missense Mutation (SNP) | VAF 193/798 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY8 | c.2631C>T p.Y877= | Silent (SNP) | VAF 215/1564 reads (14%) | catalogued as rs752869218, COSV53898678, COSV53913133; called by muse, mutect2, varscan2
- ANKRD34A | c.453A>C p.S151= | Silent (SNP) | VAF 110/522 reads (21%) | catalogued as COSV60161303; called by muse, mutect2, varscan2
- ATP1A1 | c.2658C>G p.L886= | Silent (SNP) | VAF 136/893 reads (15%) | catalogued as rs1190603759; called by muse, mutect2, varscan2
- C3orf56 | c.678C>G p.R226= | Silent (SNP) | VAF 182/568 reads (32%) | called by muse, mutect2, varscan2
- COL4A6 | c.2751T>G p.P917= | Silent (SNP) | VAF 194/785 reads (25%) | called by muse, mutect2, varscan2
- CRTC2 | c.21C>T p.N7= | Silent (SNP) | VAF 168/307 reads (55%) | catalogued as rs772606678; called by muse, mutect2, varscan2
- EML6 | c.3585C>T p.D1195= | Silent (SNP) | VAF 228/921 reads (25%) | catalogued as rs373001496; called by muse, mutect2, varscan2
- HMG20A | c.36C>T p.P12= | Silent (SNP) | VAF 92/296 reads (31%) | catalogued as rs755764606; called by muse, mutect2, varscan2
- INCENP | c.2712C>T p.G904= (on ENST00000394818 / NM_001040694.2; = p.G900= on NM_020238.3) | Silent (SNP) | VAF 137/683 reads (20%) | catalogued as rs777481722, COSV53921423; called by muse, mutect2, varscan2
- KCNG2 | c.609C>T p.R203= | Silent (SNP) | VAF 57/188 reads (30%) | called by muse, mutect2, varscan2
- KIAA2012 | c.996G>A p.R332= | Silent (SNP) | VAF 263/878 reads (30%) | called by muse, mutect2, varscan2
- MMRN1 | c.1378A>C p.R460= | Silent (SNP) | VAF 299/781 reads (38%) | called by muse, mutect2, varscan2
- MRE11 | c.987C>T p.T329= | Silent (SNP) | VAF 451/1150 reads (39%) | called by muse, mutect2, varscan2
- OR6B1 | c.462C>A p.G154= | Silent (SNP) | VAF 172/676 reads (25%) | called by muse, mutect2, varscan2
- SLC20A2 | c.1752C>T p.I584= | Silent (SNP) | VAF 322/1140 reads (28%) | catalogued as rs778556855; called by muse, mutect2, varscan2
- SOX3 | c.846G>T p.A282= | Silent (SNP) | VAF 63/223 reads (28%) | catalogued as COSV100983691; called by muse, mutect2, varscan2
- SP100 | c.1242G>A p.A414= | Silent (SNP) | VAF 118/517 reads (23%) | catalogued as rs762080146; called by muse, mutect2, varscan2
- ANKRD54 | chr22:37848456 C>T | 5'Flank (SNP) | VAF 3/39 reads (8%) | catalogued as rs1239098766; called by muse, mutect2
- ARL8A | c.372+23G>A | Intron (SNP) | VAF 85/416 reads (20%) | called by muse, mutect2, varscan2
- CABP1 | c.655-9246C>T | Intron (SNP) | VAF 164/594 reads (28%) | called by muse, mutect2, varscan2
- CCDC14 | c.231-77G>T | Intron (SNP) | VAF 46/180 reads (26%) | called by muse, varscan2
- DDX53 | c.*7G>C | 3'UTR (SNP) | VAF 92/392 reads (23%) | called by muse, mutect2, varscan2
- EOLA1 | chrX:149549874 G>A | 3'Flank (SNP) | VAF 6/25 reads (24%) | called by mutect2, varscan2
- GIT2 | c.718+18G>A | Intron (SNP) | VAF 73/307 reads (24%) | called by muse, varscan2
- HS1BP3 | c.*47T>C | 3'UTR (SNP) | VAF 69/328 reads (21%) | called by muse, mutect2, varscan2
- ITPRIP | c.*65G>T | 3'UTR (SNP) | VAF 38/74 reads (51%) | catalogued as rs895334639; called by muse, varscan2
- KCTD3 | c.*81C>A | 3'UTR (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2, varscan2
- PSD4 | c.2386+99C>T | Intron (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- RPL9 | c.*1G>T | 3'UTR (SNP) | VAF 26/728 reads (4%) | catalogued as COSV99787621; called by muse, mutect2
- RPUSD4 | c.190-88T>C | Intron (SNP) | VAF 26/146 reads (18%) | called by muse, mutect2
- SAP30BP | c.661-53G>T | Intron (SNP) | VAF 123/304 reads (40%) | called by muse, mutect2, varscan2
- TCF25 | c.354+71G>A | Intron (SNP) | VAF 40/96 reads (42%) | called by muse, mutect2, varscan2
- TNFRSF25 | c.40-29G>A | Intron (SNP) | VAF 170/335 reads (51%) | catalogued as rs773918226; called by muse, mutect2, varscan2
- VKORC1L1 | c.-47C>T | 5'UTR (SNP) | VAF 32/98 reads (33%) | called by muse, mutect2, varscan2
